Somatic mutation profile of tumor specimen MP2PRT-PATXPS-TBP1-B (aliquot MP2PRT-PATXPS-TBP1-B-1-0-D-A82B-36) from MP2PRT case MP2PRT-PATXPS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (690 days).
Specimen MP2PRT-PATXPS-TBP1-B: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3c6e977-31bf-4f80-bd8d-783f9e97a731.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATXPS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATXPS-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbd3a686-e7eb-4758-84e6-4616d5d775c1

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 150/568 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B4GALT4 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 48/481 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763214004, COSV100785859; called by muse, mutect2
- CCDC8 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 48/702 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV56772818; called by muse, mutect2
- KRT74 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 99/503 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs139298074, COSV59770408; called by muse, mutect2, varscan2
- SLIT1 | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 18/443 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1487232112, COSV56588695; called by muse, mutect2
- FRAS1 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 32/576 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- TLR6 | c.258C>T p.N86= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as rs1177281973; called by muse, mutect2
